Gene-level copy-number profile of tumor specimen TCGA-98-A538-01A from TCGA case TCGA-98-A538, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 67.6 years (24,698 days).
Specimen TCGA-98-A538-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.dfa19030-ed3f-41ab-84ff-f3f1dec839c9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-98-A538-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c699986e-ab74-4452-8a02-c80b897aaba9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 20; copy number 1: 3,347; copy number 2: 23,361; copy number 3: 21,898; copy number 4: 9,214; copy number 5: 614; copy number 6: 185; copy number 7: 843; copy number 9: 164; copy number 10: 70; copy number 11: 11; copy number 12: 46; copy number 24: 39.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-98-A538-01A-11D-A25M-01): tumor purity 0.45, ploidy 2.73, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:7,640,711–8,004,053, 2 genes (within-gene range 0–3): UMAD1, AC007161.3.
- chr7:7,906,519–7,969,903, 4 genes: RNU6-534P, CCNB2P1, AC006042.3, GLCCI1-DT.
- chr9:28,863,626–29,318,952, 5 genes: MIR876, MIR873, AL162388.2, AL162388.1, AL353684.1.
- chr18:5,463,627–5,480,975, 1 gene: AP005059.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,972 genes in 25 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:38,814–6,341,788, 86 genes, copy number 5 (broad region; genes not listed).
- chr2:38,293,954–38,536,249, 6 genes, copy number 5: ATL2, LINC02613, AC016995.1, LINC01883, RPLP0P6, AC011247.2.
- chr2:42,440,377–43,596,046, 26 genes, copy number 5 (within-gene range 3–5): AC025750.2, KCNG3, VDAC1P13, RPS13P3, MTA3, Metazoa_SRP, AC025750.1, AC074375.1, RNU6-137P, OXER1, HAAO, FTOP1, CHORDC1P1, AC016735.1, LINC01819, LINC02590, RNU6-242P, LINC02580, AC010883.2, AC010883.3, ZFP36L2, LINC01126, AC010883.1, THADA, RNU6-958P, RN7SL531P.
- chr2:46,616,416–47,387,601, 22 genes, copy number 5: CRIPT, AC020604.1, LINC01118, SOCS5, LINC01119, AC016722.1, AC016722.2, MCFD2, TTC7A, AC093732.2, AC093732.1, STPG4, AC073283.3, AC073283.1, CALM2, EPCAM-DT, AC073283.2, BCYRN1, EPCAM, RN7SKP119, MIR559, Metazoa_SRP.
- chr3:143,971,823–147,370,656, 25 genes, copy number 5 (within-gene range 4–5): DIPK2A, RNA5SP144, AC011592.1, LARP7P4, GM2AP1, RPL21P39, AC055758.2, AC055758.1, AC107021.2, AC107021.1, LNCSRLR, PLOD2, PLSCR4, AC130509.1, AC069528.1, PLSCR2, AC069528.2, PLSCR1, RNU6-428P, PLSCR5, PLSCR5-AS1, AC092957.1, LINC02010, RNU6-505P, RPL21P71.
- chr3:166,569,693–198,222,513, 622 genes, copy number 7 (broad region; genes not listed).
- chr4:68,282,461–76,421,868, 185 genes, copy number 6–11 (broad region; genes not listed).
- chr8:135,859,369–137,092,183, 1 gene, copy number 5 (within-gene range 4–5): LINC02055.
- chr8:136,237,236–138,497,261, 9 genes, copy number 5: AC023781.1, RNU6-144P, ZYXP1, AC105213.1, AC110053.1, AC046195.1, AC046195.2, AC079015.1, FAM135B.
- chr10:78,943,328–80,299,655, 54 genes, copy number 9: ZMIZ1-AS1, AL356753.1, ZMIZ1, PPIF, ZCCHC24, AL133481.1, TPRX1P1, AL133481.3, AL133481.2, EIF5AL1, BX248123.1, RPS12P18, SFTPA2, MBL3P, SFTPA3P, SFTPA1, LINC02679, AL132656.2, NUTM2B-AS1, AL132656.3, AL132656.4, BEND3P3, AL132656.1, NUTM2B, AL135925.1, NUTM2E, NPAP1P2, CTSLP6, PGGT1BP2, AL512662.1, BMS1P21, MBL1P, SFTPD, SFTPD-AS1, ZNRF2P3, DPY19L2P5, AL356095.1, C1DP3, C1DP2, C1DP4, TMEM254-AS1, AL356095.3, TMEM254, AL356095.2, RPL22P18, PLAC9, ANXA11, LINC00857, RPS12P2, AL513174.1, EIF5AP4, AL359195.2, MAT1A, ZNF519P1.
- chr10:83,911,654–84,003,479, 2 genes, copy number 9: AL390786.1, RNU1-65P.
- chr10:92,689,955–100,829,944, 177 genes, copy number 7–10 (broad region; genes not listed).
- chr11:167,784–491,399, 30 genes, copy number 6: BET1L, ODF3, AC069287.2, RIC8A, MIR6743, SIRT3, PSMD13, AC136475.10, NLRP6, AC136475.3, PGGHG, IFITM5, AC136475.6, IFITM2, AC136475.2, IFITM1, AC136475.1, IFITM3, AC136475.4, AC136475.8, AC136475.7, AC136475.5, AC136475.9, B4GALNT4, PKP3, SIGIRR, ANO9, RN7SL838P, PTDSS2, AC138230.1.
- chr11:3,671,083–3,797,792, 1 gene, copy number 5 (within-gene range 2–5): NUP98.
- chr11:3,781,395–4,368,386, 25 genes, copy number 5: RNU7-50P, PGAP2, RHOG, STIM1-AS1, STIM1, AC090587.1, MIR4687, PPIAP40, AC087441.1, AC087441.3, HNRNPA1P76, AC087441.2, RPS29P20, RRM1, RRM1-AS1, OR55B1P, LINC02749, RDXP1, SSU72P5, SSU72P2, SSU72P6, SSU72P4, SSU72P3, SSU72P7, OR52B4.
- chr11:66,244,840–71,252,577, 199 genes, copy number 7–24 (within-gene range 1–24) (broad region; genes not listed).
- chr18:21,871,446–25,818,532, 75 genes, copy number 5 (broad region; genes not listed).
- chr18:30,954,820–31,986,087, 32 genes, copy number 5: AC016382.1, RNU6-857P, DSC3, DSC2, DSCAS, DSC1, AC012417.1, DSG1, DSG1-AS1, RNU6-167P, DSG4, Y_RNA, DSG3, AC021549.1, DSG2, DSG2-AS1, TTR, B4GALT6, AC017100.1, RN7SKP44, LRRC37A7P, AC017100.2, SLC25A52, TRAPPC8, AC022960.1, AC022960.3, AC022960.2, RNU6-1050P, AC009831.1, PGDP1, AC009831.2, AC009831.4.
- chr18:45,212,995–47,594,550, 50 genes, copy number 5 (within-gene range 2–5): SLC14A2, SLC14A2-AS1, AC021517.1, AC021517.3, AC091151.2, AC091151.7, AC091151.1, AC023421.1, AC023421.2, SLC14A1, AC087685.1, SIGLEC15, EPG5, PSTPIP2, RN7SKP26, AC012569.1, RNY4P37, ATP5F1A, HAUS1, RNU6-1278P, C18orf25, RNF165, AC015959.1, AC018931.1, LOXHD1, ST8SIA5, AC090311.1, AC090241.2, AC090241.3, PIAS2, AC090241.1, AC090373.1, KATNAL2, ELOA3D, ELOA3C, ELOA3B, ELOA3, ELOA2, AC012254.5, AC012254.1, AC012254.3, HDHD2, AC012254.2, AC012254.4, IER3IP1, SKOR2, RNU6-1131P, AC051635.1, MIR4527HG, MIR4527.
- chr18:61,333,430–64,423,601, 51 genes, copy number 5 (within-gene range 2–5): CDH20, RNU6-116P, RPL30P14, AC090409.2, AC090409.1, AC105094.2, AC105094.1, LINC01544, RNF152, PIGN, RPIAP1, RELCH, AC027514.1, AC027514.2, TNFRSF11A, Y_RNA, AC100843.1, RPL17P44, AC100843.2, ACTBP9, ZCCHC2, AC064801.1, AC064801.2, RN7SL705P, PHLPP1, RNU6-142P, BCL2, AC022726.1, AC022726.2, KDSR, AC036176.1, VPS4B, AC036176.2, SERPINB5, AC036176.3, ATP5MC1P6, SERPINB12, SERPINB13, SERPINB4, SERPINB11, SERPINB3, SERPINB7, SERPINB2, SERPINB10, HMSD, AC009802.1, SERPINB8, LINC01924, RPL12P39, LINC00305, LINC01538.
- chr18:71,732,615–71,788,128, 1 gene, copy number 6 (within-gene range 2–6): LINC01899.
- chr18:72,536,680–74,523,454, 27 genes, copy number 5 (within-gene range 2–5): CBLN2, HNRNPA1P11, NETO1, AC023301.1, RNA5SP460, MIR548AV, AC091138.1, LINC02864, LINC02582, AC079070.1, RN7SL401P, AC090125.1, AC010947.1, AC090125.2, FBXO15, TIMM21, AC090398.1, RN7SL551P, CYB5A, AC090398.2, C18orf63, FAUP1, LINC01922, DIPK1C, AC009704.3, CNDP2, AC009704.2.
- chr19:42,902,086–43,504,935, 22 genes, copy number 6: PSG6, PSG7, CEACAMP7, AC004784.1, PSG11, CEACAMP8, PSG2, CEACAMP9, AC005392.1, PSG5, PSG4, CEACAMP10, PSG9, CEACAMP11, CEACAMP4, AC005392.2, CD177, AC005392.3, CD177P1, TEX101, LYPD3, PHLDB3.
- chr22:15,290,718–16,914,981, 68 genes, copy number 5 (broad region; genes not listed).
- chr22:43,400,331–50,582,965, 176 genes, copy number 5–6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,884. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
